Somatic mutation profile of tumor specimen 0DMUZG from CCDI case PBCAVJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sex cord-gonadal stromal tumor, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 5.6 years (2,045 days).
Specimen 0DMUZG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75e27459-8190-495d-91a0-f936c0646775.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWU0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/749b186d-0103-4bd2-80fa-8d936075672d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 158/287 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TMF1 | c.2201G>A p.R734K | Missense Mutation (SNP) | VAF 58/501 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.16); catalogued as COSV68373932; called by muse, varscan2
- FOXO4 | c.412T>A p.F138I | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP3K20 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 160/671 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, varscan2
- MUC3A | c.6842A>T p.E2281V | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious, low confidence (0.03); called by muse, varscan2
- PSMF1 | c.380G>C p.S127T | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- TTN | c.57546T>C p.R19182= (on ENST00000591111; = p.R11758= on NM_003319.4) | Silent (SNP) | VAF 132/330 reads (40%) | called by muse, varscan2
- STRAP | c.775+88T>A | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, varscan2
